Surgical pathology report (de-identified scan), TCGA case TCGA-49-AARE, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-AARE-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

=====

INTERPRETATION AND DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE (LOBECTOMY): INFILTRATING POORLY DIFFERENTIATED ADENOCARCINOMA (2 CM) WITH EXTENSIVE NECROSIS. PLEURAL, BRONCHIAL, VASCULAR AND ALL SURGICAL RESECTION MARGINS ARE NEGATIVE FOR TUMOR. SURROUNDING LUNG PARENCHYMA SHOWS FOCAL MILD EMPHYSEMATOUS CHANGES. SEE NOTE.
2. LYMPH NODE, R-10 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
3. LYMPH NODE, STATION 7 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
4. LYMPH NODE, R-4 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
5. PLEURAL NODULES (EXCISION): DENSE FIBROUS TISSUE WITH FOCAL ACUTE AND CHRONIC INFLAMMATION, NEGATIVE FOR TUMOR.

NOTE: The pathologic stage is pT1 N0 MX. This case was shown at the
has seen this case and
concurs.

*Electronic signature

=====

Clinical History:
RIGHT LUNG MASS.

GROSS DESCRIPTION

(Continued on next page.)

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: (R) Lung, upper lobe C34.1
J2 5/20/14

[page 2 of 4]
PART #1: FS: RIGHT UPPER LOBE, RIGHT LUNG MASS

Resident Pathologist:

FROZEN SECTION DIAGNOSIS --

FS: RIGHT UPPER LOBE, RIGHT LUNG MASS: INFILTRATING NON-SMALL
CELL CARCINOMA (2.0 CM) WITH EXTENSIVE NECROSIS.

Dictated by

The specimen is received fresh, labeled with the patient's name, [REDACTED] and designated right upper lobe. It consists of an upper lobe of lung, weighing 160 gm and measuring 14.0 x 11.0 x 2.0 cm. A firm nodule is palpated on the surface opposite the hilum. The pleura overlying this area is non-puckered and normal appearing. The remaining pleura is focally hemorrhagic, glistening and with extensive anthracotic pigmentation. Sectioning in the area of the palpated mass, shows an ill-defined gray-white and gritty mass, measuring 2.0 cm in greatest dimension. Grossly, this mass is located 0.6 cm from the pleura surface and does not appear to involve a bronchus. The mass is well-defined and freely movable from the adjacent lung parenchyma. The arteries and vessels at the hilum appear grossly normal. The pleura overlying the tumor is inked black. A representative frozen section is taken. Hilar lymph nodes are not present in the specimen. The remaining lung is pink-red with focal hemorrhage and is crepitant. Representative tumor and normal tissue are submitted for future studies to tumor bank. The remaining tumor is submitted in its entirety.

SUMMARY OF SECTIONS

1	-	FSC	-	1	(FROZEN SECTION CONTROL)
1	-	A	-	1	(BRONCHIAL MARGIN)
1	-	B	-	4	(VASCULAR MARGINS)
2	-	C&D	-	1	EACH (TUMOR)
1	-	E	-	1	(NORMAL BRONCHUS)
4	-	F-I	-	1	EACH (NORMAL LUNG)
10	-	TOTAL	-	13	

(Continued on next page.)

[page 3 of 4]
PART #2: R10, RIGHT LUNG MASS

Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name [REDACTED] and designated R10. It consists of a previously bisected firm black/pink lymph node measuring 1.0 x 1.0 x 0.6 cm. One half is submitted for future studies and the remainder is submitted for routine histology.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

PART #3: STATION 7

Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name [REDACTED] and designated station 7. It consists of one firm tan/black lymph node measuring 1.2 x 0.6 x 0.4 cm. The specimen is bisected. One half is submitted for future studies and the remainder is submitted for permanent histology.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

(Continued on next page.)

[page 4 of 4]
PART #4: R4
Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name [REDACTED] and designated R4. It consists of one firm, gray to black lymph node measuring 1.5 x 1.5 x 1.0 cm. One half is submitted for future studies and the remainder is submitted for permanent histology.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

PART #5: PLEURAL NODULES
Resident Pathologist:

Dictated by

The specimen is received fresh labeled with the patient's name [REDACTED] and designated pleural nodules. It consists of a lobular, firm, white/tan mass measuring 1.0 x 0.4 x 0.3 cm. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Source: NCI Genomic Data Commons file 50387bc0-ab2a-4e18-9d6c-d8a555b0a66d (TCGA-49-AARE.D15D2040-F72D-4913-92FC-54741F573151.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).